Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25U, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25U-01A (Primary Tumor).

[page 1 of 2]
LABORATORY SERVICES

ICD-0-3

carcinoma, hepatocellular, nos 8170/3
Site: liver C22.0

bw 4/25/11

Accession #:

Name:

Patient ID:

PHN:

ALT ID:

DOB:

Telephone:

Requesting Physician:

Encounter:

Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

ORIGINAL REPORT

SPECIMEN:

- A: Gallbladder.
- B: Portal lymph node.
- C: Right liver - 423 gm.

CLINICAL HISTORY:

Hepatocellular cancer.

DIAGNOSIS:

A: GALLBLADDER, CHOLECYSTECTOMY:

- NEGATIVE FOR MALIGNANCY.

B: PORTAL LYMPH NODE, BIOPSY:

- ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY.

C: RIGHT LIVER, PARTIAL RESECTION:

- HEPATOCELLULAR CARCINOMA, 7.3 X 6.0 X 5.8 CM.
- TUMOR IS ABOUT 0.9 CM FROM THE LIVER RESECTION MARGIN.
- FOREIGN BODY TYPE REACTIONS PRESENT IN NUMEROUS INTRAHEPATIC VESSELS, LIKELY DUE TO REACTIONS TO THE EMBOLIC PROCEDURE.
- BACKGROUND LIVER SHOW FOCAL MICROSTEATOSIS, PORTAL LYMPHOCYTIC AGGREGATION AND INFLAMMATION. THE INFLAMMATION MAY BE THE RESULT OF EMBOLIC PROCEDURE. CLINICAL CORRELATION REQUIRED.

Reported:

Reported by:

Signed by:

(Electronic Signature,

GROSS DESCRIPTION:

A: The specimen consists of a collapsed gallbladder measuring 6.4 x 2.9 x 0.7 cm. The serosa is tan and smooth apart from where it attaches to the liver bed, where it appears roughened and light green. There is a focal area of puckering the distal end of the gallbladder. It contains a minimal amount of viscous green bile. No calculi are identified. The mucosa is dark green and velvety without signs of cholesterosis. The wall thickness measures up to 0.4 cm. Representative sections of the gallbladder, including the puckered area of the wall.

FINAL

[page 2 of 2]
LABORATORY SERVICES

Accession #:
Name:
Patient ID:
PHN:
ALT ID:
DOB:
Telephone:
Requesting Physician:
Encounter:
Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

GROSS DESCRIPTION:

B: The specimen consists of a portion of fibrofatty tissue measuring 1.4 x 1.1 x 0.2 cm. Within it is a lymph node with a maximal dimension of 0.9 cm. Entirely submitted in cassette B.

C: The specimen consists of a portion of liver weighing 423 gm and measuring 16.8 x 8.9 x 7.4 cm. The outer capsule is smooth with a slightly micronodular appearance. The specimen has previously been treated with silver nitrate and the surgical margin has been inked black. The surgical margin measures 11.3 x 7.1 cm. Within the liver is a well circumscribed tan yellow nodule measuring 6.0 x 5.8 x 7.3 cm. It has a soft rubbery consistency with a central area of irregular hemorrhage. Within uninvolved parenchyma there are small areas suspicious for tumor within the vascular space. The uninvolved parenchyma is smooth, tan and has a subtle micronodular appearance. The closest tumor to the surgical margin is 0.9 cm and is within 1 mm of the capsule.

Cassette submitted as follows:

C1 through C11 - shaved margin of the surgical margin closest and farthest away.

C12 through C14 - sections of tumor with capsule.

C15 and C16 - suspicious for tumor emboli.

C17 through C19 - background liver.

Procedure:

FINAL

Source: NCI Genomic Data Commons file 64461ae0-a78c-4e0c-9f2f-ef7fd630cb00 (TCGA-G3-A25U.2781ABF5-FC79-4973-BE15-037BC685FAFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).